Surgical pathology report (de-identified scan), TCGA case TCGA-2A-AAYU, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Memorial Sloan Kettering Cancer Center, specimen TCGA-2A-AAYU-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Clinical Diagnosis & History:

PSA 7.2, cT1c, Gleason 3+3, left side disease questionable ECE left ant on MRI.

DATE OF TUMOR PROCUREMENT:

Specimens Submitted:

- 1: Prostate, seminal vesicles
- 2: Left external iliac lymph nodes
- 3: Left obturator lymph nodes
- 4: Left hypogastric lymph nodes
- 5: Right external iliac lymph nodes
- 6: Right obturator lymph nodes
- 7: Right hypogastric lymph nodes
- 8: Peri-prostatic fat

DIAGNOSIS:

1. Prostate, seminal vesicles:

Part # 1

Tumor Type:

Adenocarcinoma

Gleason's Grade:

Primary Gleason grade:3

Secondary Gleason grade:3

Total Gleason score:6

Tertiary Gleason grade: 4

Tumor Location:

Involves Right anterior

Involves Left anterior

Dominant tumor mass located in: Left anterior, from apex to base

Vascular Invasion:

Not Identified

Perineural Invasion:

Identified

Tumor Multicentricity:

Multicentric foci of invasive carcinoma are present

High Grade Prostatic Intraepithelial Neoplasia:

Identified

Capsule:

Focal extracapsular extension

The location of the extracapsular extension is Left anterior, near base

Seminal Vesicles:

Not involved

ICD-O-3

Adenocarcinoma NOS 8480/3

Site Prostate NOS C61.9

Op 3/12/14

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

Bladder Neck:

Invades bladder neck

Surgical Margins:

Tumor present at bladder neck
See note

Non-Neoplastic Prostate:

Exhibits nodular hyperplasia

Staging (AJCC 1997):

pT3a (extracapsular extension)

Note: Focus of prostatic adenocarcinoma is present on the shaved bladder neck section, involving large smooth muscle bundles. There are no adjacent benign prostatic glands. According to the AJCC 2010 staging system, microscopic involvement of bladder neck is considered as pT3a. Clinical correlation is suggested.

2. Left external iliac lymph nodes:

Part # 2

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 6

3. Left obturator lymph nodes:

Part # 3

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 1

4. Left hypogastric lymph nodes:

Part # 4

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 5

5. Right external iliac lymph nodes:

Part # 5

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 8

6. Right obturator lymph nodes:

Part # 6

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 3

7. Right hypogastric lymph nodes:

Part # 7

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 5

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

8. Peri-prostatic fat, excision:
- Benign fibroadipose tissue

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh, labeled "Prostate and seminal vesicles". It consists of a prostate and seminal vesicles. The total weight is 67.0 grams. The prostate measures 4.3 cm from apex to base, 4.5 cm transversely, and 4.5 cm from anterior to posterior. The right and left seminal vesicles measure 4.0 x 2.0 and 3.7 x 2.0 cm, respectively. The external surface of the prostate is smooth. The prostate is inked (right=green, left=blue) and fixed in formalin overnight. The prostate is serially cut from apex to base at approximately 3-4 mm intervals. The prostate is entirely submitted.

Summary of Sections:

RA-right apical margin

LA-left apical margin

BN-bladder neck margin

RSV-right seminal vesicle

LSV-left seminal vesicle

A-I -serial sections of prostate (apex to base)

2). Received in formalin labeled "left external iliac lymph node" is a 4 x 2 x 1 cm fragment of fibroadipose tissue containing multiple lymph nodes ranging from 0.3 to 3.4 cm in greatest diameter. The lymph nodes are entirely submitted.

Summary of sections:

LN - lymph nodes

BLN - bisected lymph nodes

3). Received in formalin labeled "left obturator lymph nodes" is a 2 x 2 x 1.5 cm aggregate of yellow-tan fatty adipose tissue containing a 1.6 cm gray-tan lymph node. Lymph node is entirely submitted.

Summary of sections:

LN - lymph nodes

4). Received in formalin labeled "left hypogastric lymph nodes" is a 2.3 x 1.5 x 1 cm aggregate of fatty adipose tissue containing multiple lymph nodes ranging from 0.4 to 0.7 cm in greatest diameter. The lymph nodes are entirely submitted.

Summary of sections:

LN - lymph nodes

5). Received in formalin labeled "right external iliac lymph nodes" is a 4.3 x 3.5 x 1.2 cm aggregate of fatty and adipose tissue containing multiple lymph nodes ranging from 0.3 to 1.3 cm in greatest. Lymph nodes are entirely submitted.

Summary of sections:

[page 4 of 5]
LN - lymph nodes

6). Received in formalin labeled "left on lymph nodes" is a 1.7 x 1.2 x 0.5 cm aggregate of yellow-tan adipose tissue containing a three lymph nodes ranging from 0.4 to 0.6 cm in greatest diameter. The lymph nodes are entirely submitted.

Summary of sections:

LN - lymph nodes

7). Received in formalin labeled "right hypogastric lymph nodes" is a 0.9 x 0.9 x 0.5 cm aggregate of yellow-tan tissue containing multiple lymph nodes ranging from 0.3 to 0.5 cm in greatest diameter. The lymph nodes are entirely submitted.

Summary of sections:

LN - lymph nodes

8). Received in formalin labeled "periprosthetic fat" is a 5.5 x 4.3 x 3.1 cm aggregate of yellow-tan adipose tissue. No masses, lesions, or lymph nodes identified. Representative sections are submitted.

Summary of sections:

R - representative sections, two sections each cassette

Summary of Sections:

Part 1: Prostate, seminal vesicles

Blocks	Block Designation	PCs
1	A	1
1	B	1
1	BN	1
1	C	1
1	D	1
1	E	1
1	F	1
1	G	1
1	H	1
1	I	1
1	LA	1
1	LSV	1
1	RA	1
1	RSV	1

Part 2: Left external iliac lymph nodes

Blocks	Block Designation	PCs
2	BLN	4
2	LN	5

Part 3: Left obturator lymph nodes

Blocks	Block Designation	PCs
2	LN	3

Part 4: Left hypogastric lymph nodes

Blocks	Block Designation	PCs
4	LN	4

Part 5: Right external iliac lymph nodes

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

Blocks **Block Designation** **PCs**
4 LN 8

Part 6: Right obturator lymph nodes

Blocks **Block Designation** **PCs**
2 LN 4

Part 7: Right hypogastric lymph nodes

Blocks **Block Designation** **PCs**
2 LN 2

Part 8: Peri-prostatic fat

Blocks **Block Designation** **PCs**
3 R 6

Special Studies:

Result

Special Stain
RECUT

Comment

Source: NCI Genomic Data Commons file 99eec17a-9fe1-44af-b94e-22d48e741ac5 (TCGA-2A-AAYU.6CD9378F-F5A6-4214-8685-3D56ED6ADB0B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).